Surgical pathology report (de-identified scan), TCGA case TCGA-F4-6460, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Asterand, specimen TCGA-F4-6460-01A (Primary Tumor).

LARGE INTESTINE TISSUE CHECKLIST

Specimen type: Excision of tumor
Specimen size: Not specified
Tumor site: Sigmoid colon
Tumor size: 4 x 3 x 1 cm
Tumor features: None specified
Histologic type: Adenocarcinoma
Histologic grade: Moderately differentiated
Tumor extent: Pericolonic tissues
Lymph nodes: 1/6 positive for metastasis (Intraabdominal 1/6)
Margins: Uninvolved
Evidence of neo-adjuvant treatment: Not specified
Additional pathologic findings: Not specified
Comments: None

Source: NCI Genomic Data Commons file 90c331ed-164b-4b96-9f93-aff2ebeb8b56 (TCGA-F4-6460.037E666E-3821-4A1C-931E-C92FA5657F48.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).